Somatic mutation profile of tumor specimen TCGA-AY-A54L-01A (aliquot TCGA-AY-A54L-01A-11D-A28G-10) from TCGA case TCGA-AY-A54L, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Hepatic flexure of colon; AJCC pathologic stage: Stage I; Age at diagnosis: 74.1 years (27,074 days).
Specimen TCGA-AY-A54L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6831a61d-d66f-40b2-b7b0-8b751ff55e28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AY-A54L-10A (Blood Derived Normal), aliquot TCGA-AY-A54L-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b793ef6-560c-4369-a0b6-9edd60b05f58

The open-access MAF lists 160 somatic variants for this specimen: 122 protein-altering or splice-affecting, 26 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 26, Nonsense Mutation 9, Frame Shift Del 7, 3'UTR 4, RNA 4, Splice Site 4, Intron 3, Frame Shift Ins 3, Splice Region 3, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1548+1G>A p.X516_splice | Splice Site (SNP) | VAF 28/112 reads (25%) | catalogued as rs1114167599, CS020798, CS020799, COSV57403470, COSV99965848; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4290del p.M1431Cfs*42 | Frame Shift Del (DEL) | VAF 41/123 reads (33%) | catalogued as rs1554085714; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 39/105 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABHD16A | c.1308-6C>G | Splice Region (SNP) | VAF 20/118 reads (17%) | catalogued as COSV65451392, COSV65452097; called by muse, mutect2, varscan2
- ACSM5 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs1319148619, COSV59375753; called by muse, mutect2, varscan2
- AL592490.1 | c.932G>C p.S311T | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69424687; called by muse, mutect2, varscan2
- AMPD1 | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146036570; called by muse, mutect2, varscan2
- BAHCC1 | c.6101del p.P2034Lfs*15 | Frame Shift Del (DEL) | VAF 67/132 reads (51%) | catalogued as COSV57035584; called by mutect2, pindel, varscan2
- CACNA1E | c.3712G>T p.A1238S | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62386270; called by muse, mutect2
- CALCR | c.1307G>A p.R436H (on ENST00000649521 / NM_001164737.2; = p.R420H on NM_001742.4) | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV64006033; called by muse, mutect2, varscan2
- CAMTA1 | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV57884348; called by muse, mutect2, varscan2
- CBFA2T2 | c.845G>A p.G282D | Missense Mutation (SNP) | VAF 142/240 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as rs762596928; called by muse, mutect2
- CCN5 | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV51935909; called by muse, mutect2, varscan2
- CDCA2 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.59); catalogued as rs1480702877; called by muse, mutect2, varscan2
- CDK5RAP3 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV58114281; called by muse, mutect2
- COL25A1 | c.718G>T p.G240W | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1296787744; called by mutect2, varscan2
- COL4A2 | c.4322G>A p.G1441E | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64625101; called by muse, mutect2, varscan2
- COL6A6 | c.3079G>T p.V1027F | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1428028752; called by muse, varscan2
- CREBBP | c.3307C>T p.R1103* | Nonsense Mutation (SNP) | VAF 36/121 reads (30%) | catalogued as CM148332, COSV52133173; called by muse, varscan2
- CSMD3 | c.8614+1G>A p.X2872_splice (on ENST00000297405 / NM_001363185.1; = p.X2703_splice on NM_052900.3) | Splice Site (SNP) | VAF 37/102 reads (36%) | catalogued as COSV99826963; called by muse, mutect2, varscan2
- CTAG2 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV55994700, COSV55996639; called by muse, mutect2
- DNAH5 | c.3426A>T p.K1142N | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99445894; called by muse, mutect2
- DNAI3 | c.2200G>A p.G734S | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs958819492; called by muse, mutect2, varscan2
- DOCK3 | c.5216G>A p.S1739N | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99809705; called by muse, mutect2
- EBF3 | c.1574G>T p.S525I | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs982052126, COSV62472198; called by muse, mutect2, varscan2
- ELAC2 | c.335G>C p.R112P | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62032579; called by muse, mutect2, varscan2
- EPB41 | c.2143C>T p.R715* (on ENST00000343067 / NM_001166005.2; = p.R473* on NM_004437.4) | Nonsense Mutation (SNP) | VAF 26/132 reads (20%) | catalogued as COSV58041166; called by muse, mutect2, varscan2
- F10 | c.1087G>A p.G363S | Missense Mutation (SNP) | VAF 111/261 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM000379, COSV65020824; called by muse, mutect2, varscan2
- FBXW7 | c.1958C>T p.T653M (on ENST00000281708 / NM_001349798.2; = p.T573M on NM_018315.5) | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs775781675, COSV55893550, COSV99029476; called by muse, mutect2, varscan2
- GJB1 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs748095370, CM145386; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR68 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752894280; called by muse, mutect2, varscan2
- HCN1 | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV57512465; called by muse, mutect2, varscan2
- HDAC8 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs148688742, COSV101003363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV2-5 | c.47-1G>T p.X16_splice | Splice Site (SNP) | VAF 29/206 reads (14%) | catalogued as rs112204392; called by muse, mutect2, varscan2
- INPP4A | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs764715229, COSV50864819; called by muse, mutect2, varscan2
- KCNAB2 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as rs746056849, COSV51239293; called by muse, mutect2, varscan2
- KCNQ3 | c.832C>T p.L278F | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66463128; called by muse, mutect2, varscan2
- KRT72 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs766532753, COSV53373404; called by muse, mutect2, varscan2
- KRTAP6-3 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 9/89 reads (10%) | PolyPhen probably damaging (0.97); catalogued as COSV101196471; called by muse, mutect2
- MAGEB2 | c.494G>C p.G165A | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs1204421619; called by muse, mutect2, varscan2
- MPPED1 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); catalogued as rs749639689, COSV68837441; called by muse, mutect2, varscan2
- MRPL28 | c.658_660del p.E220del | In Frame Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs754425743; called by pindel, varscan2
- MRPS27 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1554057195, COSV54648819; called by muse, mutect2, varscan2
- OR4C16 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV58940833; called by muse, mutect2, varscan2
- OR5P3 | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV60428966; called by muse, mutect2, varscan2
- PAPOLA | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV53483221; called by muse, mutect2, varscan2
- PAPPA2 | c.4045C>T p.R1349W | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs758198387, COSV62792453; called by muse, mutect2, varscan2
- PCBP1 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, varscan2
- PCDH11X | c.610C>A p.Q204K | Missense Mutation (SNP) | VAF 28/802 reads (3%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.998); catalogued as COSV100009027; called by muse, mutect2
- PCDHGA2 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.012); catalogued as COSV53903734; called by muse, varscan2
- PCSK9 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs865914100, COSV100134964; called by muse, mutect2, varscan2
- PHLPP2 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV62424970; called by muse, mutect2, varscan2
- PNPLA7 | c.3443C>T p.T1148M | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53004945; called by muse, mutect2, varscan2
- PODN | c.1286G>A p.R429H (on ENST00000395871; = p.R381H on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as rs550865360, COSV57011894; called by mutect2, varscan2
- PPP1R13B | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 65/125 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs1026777873; called by muse, mutect2, varscan2
- PRR23C | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.098); catalogued as rs1363025344; called by muse, mutect2, varscan2
- PRRX1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs780981143, CM143961, COSV53411170; called by muse, mutect2, varscan2
- PSMF1 | c.762C>T p.P254= | Splice Region (SNP) | VAF 36/145 reads (25%) | catalogued as rs150771213; called by muse, mutect2, varscan2
- PUM2 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as rs755642393, COSV57586164; called by muse, mutect2, varscan2
- SALL1 | c.3772G>A p.G1258S | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs766775180; called by muse, mutect2, varscan2
- SEC14L3 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs774222918; called by muse, mutect2, varscan2
- SLC2A3 | c.1069-1G>C p.X357_splice | Splice Site (SNP) | VAF 80/165 reads (48%) | catalogued as COSV50000635, COSV50001803; called by muse, mutect2, varscan2
- SLC38A10 | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV99917232; called by muse, mutect2
- SMARCA1 | c.1185G>C p.L395F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1455446162; called by muse, mutect2
- TET2 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs771996203, COSV54437989; called by muse, mutect2, varscan2
- TMEM259 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.413); catalogued as rs771672096; called by muse, mutect2, varscan2
- TP53 | c.723del p.C242Afs*5 | Frame Shift Del (DEL) | VAF 82/187 reads (44%) | catalogued as COSV53025058, COSV53153033, COSV53211006; called by mutect2, pindel, varscan2
- TRDN | c.1483A>C p.K495Q | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100521051, COSV62134559; called by muse, varscan2
- TRERF1 | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs928875702, COSV61670535; called by muse, varscan2
- TYW1 | c.1078C>T p.L360F | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV100658450; called by muse, mutect2, varscan2
- USP7 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV100784010; called by muse, mutect2
- VWDE | c.1456G>T p.G486* | Nonsense Mutation (SNP) | VAF 9/209 reads (4%) | catalogued as COSV99280253; called by muse, mutect2
- WASHC2C | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393940516, COSV60491243; called by mutect2, varscan2
- WDR91 | c.1753G>A p.V585I | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as rs974637219, COSV60371541; called by muse, mutect2, varscan2
- ZNF548 | c.862A>T p.K288* | Nonsense Mutation (SNP) | VAF 19/119 reads (16%) | catalogued as COSV60240356, COSV60242032; called by muse, mutect2, varscan2
- ZNF804B | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as rs781202005, COSV60814724; called by muse, mutect2, varscan2
- ZRANB1 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62841529; called by muse, mutect2, varscan2
- ZSWIM8 | c.2948G>A p.R983H (on ENST00000605216 / NM_001242487.2; = p.R988H on NM_015037.3) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs542136079, COSV67131207; called by muse, mutect2, varscan2
- ABHD11 | c.211T>G p.F71V | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ACIN1 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- AHNAK2 | c.11363del p.D3788Afs*9 | Frame Shift Del (DEL) | VAF 22/151 reads (15%) | called by mutect2, varscan2
- AHNAK2 | c.11362del p.D3788Tfs*9 | Frame Shift Del (DEL) | VAF 18/139 reads (13%) | called by mutect2*, pindel, varscan2*
- ARHGAP36 | c.1588C>T p.L530F | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASB15 | c.921T>A p.S307R | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATP10D | c.1664T>A p.L555H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2CD5 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- CBL | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.32); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- CFAP45 | c.1619G>T p.R540L | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CPA3 | c.261G>T p.M87I | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CRAMP1 | c.776dup p.C260Lfs*4 | Frame Shift Ins (INS) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- ENOX2 | c.851G>A p.R284H (on ENST00000338144 / NM_001382520.1; = p.R255H on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- EXOC2 | c.2659C>T p.L887F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EYS | c.5960C>T p.T1987I | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- IDE | c.1687C>G p.Q563E | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- ITGA5 | c.1195del p.L399Wfs*26 | Frame Shift Del (DEL) | VAF 55/190 reads (29%) | called by mutect2, pindel, varscan2
- KCNJ3 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- LPL | c.937C>A p.L313M | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.063); called by muse, mutect2
- MSANTD3 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 22/188 reads (12%) | called by muse, mutect2, varscan2
- MTO1 | c.1844C>A p.S615* (on ENST00000370300 / NM_133645.3; = p.S590* on NM_012123.4) | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- MYO1F | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NSUN3 | c.676T>C p.S226P | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NT5C1B | c.1229C>A p.T410N (on ENST00000359846 / NM_001199086.2; = p.T350N on NM_033253.4) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OGDHL | c.1175C>G p.S392C | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- RANBP3L | c.288dup p.M97Yfs*9 | Frame Shift Ins (INS) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- RASGRF1 | c.3190G>T p.G1064* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- RELCH | c.2011A>G p.I671V | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- RNF17 | c.3894T>C p.P1298= | Splice Region (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- SACS | c.9980C>A p.A3327D | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- SAMD9 | c.4145C>A p.S1382* | Nonsense Mutation (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
- SLC25A53 | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 44/495 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.404); called by muse, mutect2
- SMG7 | c.1594A>C p.N532H | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); called by muse, mutect2
- SOX9 | c.1185_1186dup p.H396Rfs*8 | Frame Shift Ins (INS) | VAF 8/80 reads (10%) | called by mutect2, pindel
- STRIP2 | c.487G>T p.G163W | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SVEP1 | c.3719G>T p.C1240F | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYNE1 | c.22571A>G p.Q7524R (on ENST00000367255 / NM_182961.4; = p.Q7453R on NM_033071.3) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TFEC | c.432C>A p.H144Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPC5 | c.2724A>C p.E908D | Missense Mutation (SNP) | VAF 87/250 reads (35%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- YWHAZ | c.344_345del p.K115Sfs*16 | Frame Shift Del (DEL) | VAF 61/193 reads (32%) | called by mutect2, pindel, varscan2
- ZNF251 | c.1454G>T p.G485V | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF420 | c.1783G>T p.A595S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ZNF610 | c.35C>A p.A12E | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ZNF831 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 18/145 reads (12%) | called by muse, mutect2, varscan2
- ACTBL2 | c.1110C>A p.I370= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as rs770710606; called by mutect2, varscan2
- AHNAK2 | c.7719T>C p.S2573= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV60908502; called by muse, mutect2, varscan2
- ANOS1 | c.1518G>C p.R506= | Silent (SNP) | VAF 14/361 reads (4%) | catalogued as rs1569252472, CD070475, COSV52922303, COSV99390517; called by muse, mutect2
- CABLES1 | c.1644C>T p.L548= (on ENST00000256925 / NM_001100619.2; = p.L283= on NM_138375.2) | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as rs367970943; called by muse, mutect2, varscan2
- CAND1 | c.924T>C p.D308= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- CDH6 | c.2196C>T p.Y732= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as rs1213304652, COSV54068459; called by muse, mutect2
- DSPP | c.1785T>C p.S595= | Silent (SNP) | VAF 87/416 reads (21%) | called by muse, varscan2
- DZIP1L | c.2136G>A p.K712= | Silent (SNP) | VAF 35/114 reads (31%) | called by muse, mutect2, varscan2
- EHMT1 | c.3084C>T p.A1028= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs1184645526; called by muse, mutect2, varscan2
- ESRRB | c.228C>T p.Y76= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as rs1473350541, COSV55058079; called by muse, mutect2, varscan2
- FAM47C | c.1320G>A p.P440= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as rs782336183, COSV100792752, COSV100792913; called by muse, mutect2, varscan2
- HNRNPA1 | c.681C>T p.G227= | Silent (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- KCNK10 | c.315C>T p.I105= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs749627443, COSV100067096; called by muse, mutect2, varscan2
- LRRN1 | c.909C>T p.V303= | Silent (SNP) | VAF 74/140 reads (53%) | catalogued as rs201020382, COSV60014612; called by muse, mutect2, varscan2
- MAP1B | c.3786T>G p.S1262= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV99701914; called by muse, mutect2
- MET | c.2499C>A p.L833= | Silent (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- MUC17 | c.9081T>G p.S3027= | Silent (SNP) | VAF 18/186 reads (10%) | called by muse, mutect2
- MYL10 | c.345G>A p.A115= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as rs375406824, COSV56207128; called by muse, mutect2, varscan2
- NES | c.3510G>A p.E1170= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs1465748494, COSV100957769; called by muse, mutect2
- NRK | c.1983G>A p.P661= | Silent (SNP) | VAF 24/199 reads (12%) | catalogued as rs368670973; called by muse, mutect2, varscan2
- PCDH19 | c.1665C>T p.D555= | Silent (SNP) | VAF 33/283 reads (12%) | called by muse, mutect2, varscan2
- PTPRU | c.2823C>T p.A941= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs374111722; called by muse, mutect2, varscan2
- SHROOM3 | c.3624G>A p.E1208= | Silent (SNP) | VAF 28/128 reads (22%) | called by muse, varscan2
- SLC32A1 | c.1311C>T p.C437= | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as COSV54146366; called by muse, mutect2, varscan2
- SULT6B1 | c.546T>C p.Y182= (on ENST00000535679 / NM_001367551.1; = p.Y144= on NM_001032377.2) | Silent (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- WASHC2A | c.1119G>A p.E373= | Silent (SNP) | VAF 84/495 reads (17%) | catalogued as COSV99254496; called by muse, mutect2, varscan2
- ABCA1 | c.720+2704G>C | Intron (SNP) | VAF 37/67 reads (55%) | called by muse, mutect2, varscan2
- BHLHE22 | c.*248_*249insC | 3'UTR (INS) | VAF 45/188 reads (24%) | catalogued as COSV100417629; called by mutect2, pindel, varscan2
- CCDC140 | n.473C>T | RNA (SNP) | VAF 54/297 reads (18%) | catalogued as COSV54674792; called by muse, mutect2, varscan2
- CHCHD2P9 | n.450G>C | RNA (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- FBXW7 | c.501+29011C>T | Intron (SNP) | VAF 16/109 reads (15%) | catalogued as rs1195624324; called by muse, mutect2, varscan2
- GPR17 | c.*783C>T | 3'UTR (SNP) | VAF 26/58 reads (45%) | catalogued as rs762560756, COSV99760438; called by muse, mutect2, varscan2
- IGHA1 | chr14:105704514 G>A | 3'Flank (SNP) | VAF 78/268 reads (29%) | called by muse, varscan2
- MIR518F | n.53G>T | RNA (SNP) | VAF 60/112 reads (54%) | catalogued as rs1390515076; called by muse, mutect2, varscan2
- MRRFP1 | n.71C>T | RNA (SNP) | VAF 36/306 reads (12%) | catalogued as rs770204046; called by muse, mutect2, varscan2
- OR2L13 | c.*178T>C | 3'UTR (SNP) | VAF 3/9 reads (33%) | catalogued as COSV100813686; called by muse, mutect2
- PSTPIP2 | c.*4C>A | 3'UTR (SNP) | VAF 31/143 reads (22%) | called by muse, mutect2, varscan2
- TPM2 | c.563+202G>T | Intron (SNP) | VAF 140/267 reads (52%) | called by muse, mutect2, varscan2
